Somatic mutation profile of tumor specimen TCGA-FE-A3PB-01A (aliquot TCGA-FE-A3PB-01A-11D-A21Z-08) from TCGA case TCGA-FE-A3PB, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 33.2 years (12,136 days).
Specimen TCGA-FE-A3PB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6938a3ee-6ca5-4691-9287-c8b72c12a89a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A3PB-10A (Blood Derived Normal), aliquot TCGA-FE-A3PB-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbdc1ac2-5389-48d0-a11d-c1df7a922420

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PCDHGB3 | c.188C>T p.T63I | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.139); catalogued as rs1455382111, COSV54029886; called by muse, mutect2, varscan2
- TAS2R7 | c.214T>C p.Y72H | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV53690646; called by muse, mutect2, varscan2
